Somatic mutation profile of tumor specimen ALCH-B2CT-TTP1-A (aliquot ALCH-B2CT-TTP1-A-1-0-D-A77Z-36) from ALCHEMIST case ALCH-B2CT, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Non-small cell carcinoma; Age at diagnosis: 67.6 years (24,686 days).
Specimen ALCH-B2CT-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4b6a3076-385c-42ac-b953-c19fbf9dc801.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2CT-NB1-A (Blood Derived Normal), aliquot ALCH-B2CT-NB1-A-1-0-D-A77Z-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fcb32363-d35a-4d8b-ad27-b74343a3b03b

The open-access MAF lists 387 somatic variants for this specimen: 284 protein-altering or splice-affecting, 61 silent, 42 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 239, Silent 61, Intron 17, Nonsense Mutation 16, Splice Site 13, 3'UTR 11, Frame Shift Del 8, RNA 7, Splice Region 6, 5'Flank 3, In Frame Del 2, 3'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.329G>T p.R110L | Missense Mutation (SNP) | VAF 87/167 reads (52%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.343); catalogued as rs11540654, CM115383, CM134053, CM984590, COSV52662399, COSV52668419, COSV52680444, COSV53132492; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADRA1A | c.1174G>C p.D392H | Missense Mutation (SNP) | VAF 22/310 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as COSV52366575, COSV99372034; called by muse, mutect2
- AFF2 | c.2691-1G>T p.X897_splice | Splice Site (SNP) | VAF 37/126 reads (29%) | catalogued as COSV99661330; called by muse, mutect2, varscan2
- AGTRAP | c.195C>G p.I65M | Missense Mutation (SNP) | VAF 28/268 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.341); catalogued as COSV58668818; called by muse, mutect2, varscan2
- ANO5 | c.2227G>T p.A743S | Missense Mutation (SNP) | VAF 18/476 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.297); catalogued as COSV61088059; called by muse, mutect2
- BEND6 | c.268C>T p.R90* | Nonsense Mutation (SNP) | VAF 19/189 reads (10%) | catalogued as rs928555916, COSV66070555; called by muse, mutect2
- BSN | c.3191A>G p.Q1064R | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs1359242791; called by muse, mutect2, varscan2
- BTN2A2 | c.1171G>A p.V391M | Missense Mutation (SNP) | VAF 131/464 reads (28%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.787); catalogued as rs372254650, COSV61857537; called by muse, mutect2, varscan2
- CDH10 | c.1830C>G p.S610R | Missense Mutation (SNP) | VAF 163/548 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100049914; called by muse, mutect2, varscan2
- CELSR2 | c.3482C>T p.P1161L | Missense Mutation (SNP) | VAF 101/273 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.083); catalogued as rs774502637, COSV99603272; called by muse, mutect2, varscan2
- CNPY4 | c.206A>G p.D69G | Missense Mutation (SNP) | VAF 15/338 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1364106198; called by muse, mutect2
- CNTNAP5 | c.2931C>A p.H977Q | Missense Mutation (SNP) | VAF 51/242 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV70470078; called by muse, mutect2, varscan2
- CPA6 | c.953G>T p.R318M | Missense Mutation (SNP) | VAF 22/473 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as COSV99912660; called by muse, mutect2
- CSF2RB | c.1317G>T p.V439= | Splice Region (SNP) | VAF 93/744 reads (13%) | catalogued as COSV53256961; called by muse, mutect2, varscan2
- CSMD3 | c.10870C>A p.H3624N (on ENST00000297405 / NM_001363185.1; = p.H3455N on NM_052900.3) | Missense Mutation (SNP) | VAF 34/192 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.043); catalogued as COSV52186591; called by muse, varscan2
- CTNNA2 | c.122C>G p.T41R | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.081); catalogued as COSV100781809; called by muse, mutect2
- DBT | c.16A>G p.M6V | Missense Mutation (SNP) | VAF 42/754 reads (6%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs749693779, COSV64496562; called by muse, mutect2
- DDB1 | c.3355G>A p.G1119S | Missense Mutation (SNP) | VAF 30/555 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs1350648265; called by muse, mutect2
- DNAH3 | c.6613C>T p.R2205C | Missense Mutation (SNP) | VAF 31/164 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369563636, COSV54508265, COSV54528865; called by muse, mutect2, varscan2
- DNAH8 | c.5943G>A p.M1981I | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as rs765618018; ClinVar: uncertain significance; called by muse, varscan2
- EGLN2 | c.907G>T p.G303C | Missense Mutation (SNP) | VAF 83/459 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.645); catalogued as rs1234683261, COSV58279712; called by muse, mutect2, varscan2
- ERAL1 | c.1010C>T p.A337V | Missense Mutation (SNP) | VAF 30/388 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.04); catalogued as rs771442717; called by muse, mutect2
- FANCC | c.916G>T p.D306Y | Missense Mutation (SNP) | VAF 149/666 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV56664631; called by muse, mutect2, varscan2
- FOXD4 | c.590G>A p.R197K | Missense Mutation (SNP) | VAF 110/1407 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs369349692; called by muse, mutect2
- GJA8 | c.526C>T p.R176W | Missense Mutation (SNP) | VAF 278/750 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.298); catalogued as rs372038463; called by muse, mutect2, varscan2
- GOLGA6L2 | c.2687C>A p.A896E | Missense Mutation (SNP) | VAF 86/209 reads (41%) | SIFT deleterious, low confidence (0); catalogued as rs565521161; called by muse, mutect2, varscan2
- HMCN1 | c.4816C>T p.P1606S | Missense Mutation (SNP) | VAF 32/640 reads (5%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.458); catalogued as rs776501578; called by muse, mutect2
- HOXA2 | c.368G>A p.G123D | Missense Mutation (SNP) | VAF 112/460 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.071); catalogued as rs894512210; called by muse, varscan2
- HOXB9 | c.709C>T p.R237W | Missense Mutation (SNP) | VAF 112/436 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758737820; called by muse, mutect2, varscan2
- ICE1 | c.1249G>C p.E417Q | Missense Mutation (SNP) | VAF 62/258 reads (24%) | SIFT tolerated (0.5); PolyPhen benign (0.277); catalogued as rs756591548; called by muse, mutect2, varscan2
- IGF2R | c.2509G>T p.D837Y | Missense Mutation (SNP) | VAF 77/220 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.36); catalogued as rs1295675297; called by muse, mutect2, varscan2
- IGSF3 | c.434C>A p.S145Y | Missense Mutation (SNP) | VAF 50/170 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as COSV59589199; called by muse, mutect2, varscan2
- KCNH6 | c.2207G>A p.G736D | Missense Mutation (SNP) | VAF 69/377 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs139684057; called by muse, mutect2, varscan2
- KMT2D | c.13705A>G p.I4569V | Missense Mutation (SNP) | VAF 24/172 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs745652015, COSV99987849; called by muse, mutect2, varscan2
- LAMA2 | c.5023G>A p.A1675T | Missense Mutation (SNP) | VAF 263/909 reads (29%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.511); catalogued as rs1420007591; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LRP2 | c.5014C>T p.H1672Y | Missense Mutation (SNP) | VAF 128/370 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.65); catalogued as rs1209576079; called by muse, mutect2, varscan2
- LRRTM1 | c.660C>G p.D220E | Missense Mutation (SNP) | VAF 12/382 reads (3%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as COSV99701876; called by muse, mutect2
- MAP2 | c.2374G>T p.A792S | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV52307669; called by muse, mutect2, varscan2
- MOS | c.380C>A p.T127K | Missense Mutation (SNP) | VAF 62/255 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.947); catalogued as rs766028889, COSV100322798; called by muse, mutect2, varscan2
- MPL | c.1070G>T p.R357L | Missense Mutation (SNP) | VAF 109/442 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as COSV65244294; called by muse, mutect2, varscan2
- MSR1 | c.104-1G>C p.X35_splice | Splice Site (SNP) | VAF 27/235 reads (11%) | catalogued as COSV100026868, COSV50513363; called by muse, mutect2, varscan2
- NCAM1 | c.328G>A p.V110I | Missense Mutation (SNP) | VAF 30/247 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.074); catalogued as rs782700835, COSV57517344; called by muse, mutect2, varscan2
- NCSTN | c.1568A>G p.Y523C | Missense Mutation (SNP) | VAF 230/1013 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs202209583; called by muse, mutect2, varscan2
- NEB | c.15794G>T p.R5265L | Missense Mutation (SNP) | VAF 42/166 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); catalogued as COSV51276264; called by muse, mutect2, varscan2
- NLRC4 | c.1358G>A p.R453Q | Missense Mutation (SNP) | VAF 81/189 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs200929188, COSV61592076; called by muse, mutect2, varscan2
- NOL6 | c.1783G>A p.G595R | Missense Mutation (SNP) | VAF 74/358 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs558572103, COSV53041146; called by muse, mutect2, varscan2
- OR10J3 | c.740C>G p.T247R | Missense Mutation (SNP) | VAF 119/680 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV59955299, COSV59955502; called by muse, mutect2, varscan2
- OR2C3 | c.485C>A p.T162K | Missense Mutation (SNP) | VAF 192/400 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.551); catalogued as rs562326145, COSV63574257, COSV63574402, COSV63574958; called by muse, mutect2, varscan2
- OR2L13 | c.800C>A p.P267Q | Missense Mutation (SNP) | VAF 251/739 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV63556476; called by muse, mutect2, varscan2
- OR2M5 | c.62G>T p.S21I | Missense Mutation (SNP) | VAF 46/275 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.563); catalogued as COSV100822708; called by muse, mutect2, varscan2
- OR2T34 | c.61G>T p.G21* | Nonsense Mutation (SNP) | VAF 196/802 reads (24%) | catalogued as COSV100170476; called by muse, varscan2
- OR2W1 | c.885G>C p.K295N | Missense Mutation (SNP) | VAF 28/127 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.735); catalogued as rs7341215, COSV65851800; called by muse, mutect2, varscan2
- OR4C46 | c.331A>G p.I111V | Missense Mutation (SNP) | VAF 99/308 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.081); catalogued as rs1374991100; called by muse, mutect2, varscan2
- PABPC5 | c.838C>T p.R280C | Missense Mutation (SNP) | VAF 13/173 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57039494; called by muse, mutect2
- PAPPA2 | c.1136A>G p.Y379C | Missense Mutation (SNP) | VAF 59/286 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62781042; called by muse, mutect2, varscan2
- PGLYRP1 | c.408G>T p.M136I | Missense Mutation (SNP) | VAF 54/168 reads (32%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.511); catalogued as COSV99151492; called by muse, mutect2, varscan2
- PKHD1L1 | c.2981G>T p.G994V | Missense Mutation (SNP) | VAF 104/416 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101005035; called by muse, mutect2, varscan2
- PLCH1 | c.2802G>T p.M934I (on ENST00000340059 / NM_001130960.2; = p.M926I on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 160/697 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as rs1409242892; called by muse, mutect2, varscan2
- PLEC | c.4718A>T p.K1573M (on ENST00000322810 / NM_201380.4; = p.K1463M on NM_000445.5) | Missense Mutation (SNP) | VAF 44/629 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV100511973; called by muse, mutect2
- PLPPR2 | c.694G>A p.G232S | Missense Mutation (SNP) | VAF 102/382 reads (27%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.992); catalogued as rs1230625985; called by muse, mutect2, varscan2
- PLXND1 | c.2296G>T p.G766C | Missense Mutation (SNP) | VAF 40/376 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100138999; called by muse, mutect2, varscan2
- PPFIBP1 | c.1509G>T p.R503S (on ENST00000318304 / NM_177444.3; = p.R486S on NM_003622.4) | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV99944843; called by muse, mutect2, varscan2
- PSMD2 | c.788C>T p.P263L | Missense Mutation (SNP) | VAF 102/517 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.247); catalogued as COSV59530058; called by muse, mutect2, varscan2
- PTPRM | c.4142G>T p.G1381V | Missense Mutation (SNP) | VAF 18/289 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99046030; called by muse, mutect2
- RB1 | c.1060_1061del p.Q354Efs*7 | Frame Shift Del (DEL) | VAF 50/160 reads (31%) | catalogued as rs587778829; called by pindel, varscan2
- RBM12B | c.1102G>A p.A368T | Missense Mutation (SNP) | VAF 20/210 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.023); catalogued as COSV66968396; called by muse, mutect2
- RFX7 | c.224C>A p.S75Y (on ENST00000559447 / NM_001368074.1; = p.S172Y on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/120 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100429225; called by muse, mutect2, varscan2
- ROCK1 | c.917C>G p.S306* | Nonsense Mutation (SNP) | VAF 11/107 reads (10%) | catalogued as COSV101296291; called by muse, varscan2
- RORC | c.1120C>T p.R374C | Missense Mutation (SNP) | VAF 57/372 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.647); catalogued as rs750446790, COSV59092251; called by muse, mutect2, varscan2
- RSPH14 | c.691G>T p.D231Y | Missense Mutation (SNP) | VAF 124/344 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.852); catalogued as rs756623949; called by muse, mutect2, varscan2
- RTF1 | c.2101G>A p.E701K | Missense Mutation (SNP) | VAF 92/235 reads (39%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.587); catalogued as COSV67478956; called by muse, mutect2, varscan2
- SEMA3D | c.337C>T p.R113W | Missense Mutation (SNP) | VAF 50/282 reads (18%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.956); catalogued as rs200513307; called by muse, mutect2, varscan2
- SHOX | c.171G>T p.Q57H | Missense Mutation (SNP) | VAF 313/799 reads (39%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV100478728; called by muse, mutect2, varscan2
- SLC6A5 | c.210C>G p.C70W | Missense Mutation (SNP) | VAF 46/482 reads (10%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV54227290; called by muse, mutect2
- SPHKAP | c.1412C>T p.P471L | Missense Mutation (SNP) | VAF 19/142 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as rs1192736151; called by muse, mutect2, varscan2
- SSTR5 | c.197T>A p.L66Q | Missense Mutation (SNP) | VAF 212/776 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99559750; called by muse, mutect2, varscan2
- STRA6 | c.789-1G>T p.X263_splice | Splice Site (SNP) | VAF 185/483 reads (38%) | catalogued as COSV60588045; called by muse, mutect2, varscan2
- SYCP2L | c.752A>G p.H251R | Missense Mutation (SNP) | VAF 36/179 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.16); catalogued as rs780095117; called by muse, varscan2
- SYT5 | c.446G>A p.R149Q | Missense Mutation (SNP) | VAF 36/422 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.207); catalogued as COSV62830182; called by muse, mutect2
- TLR6 | c.859A>T p.T287S | Missense Mutation (SNP) | VAF 34/224 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.133); catalogued as COSV67935786; called by muse, mutect2, varscan2
- TMEM132B | c.1113G>T p.E371D | Missense Mutation (SNP) | VAF 44/160 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV54745418; called by muse, mutect2
- WDPCP | c.344G>T p.R115L | Missense Mutation (SNP) | VAF 73/550 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.082); catalogued as COSV99705088; called by muse, mutect2, varscan2
- XYLT1 | c.139G>C p.G47R | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as rs760732431; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- YBX1 | c.535G>T p.E179* | Nonsense Mutation (SNP) | VAF 13/155 reads (8%) | catalogued as COSV58439912; called by muse, mutect2
- ZNF831 | c.670C>A p.P224T | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.5); PolyPhen benign (0.006); catalogued as COSV64045131; called by muse, mutect2, varscan2
- ABCA12 | c.1782G>T p.E594D (on ENST00000272895 / NM_173076.3; = p.E276D on NM_015657.3) | Missense Mutation (SNP) | VAF 67/383 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.22); called by muse, mutect2, varscan2
- ABCC12 | c.181A>T p.T61S | Missense Mutation (SNP) | VAF 50/198 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- ACIN1 | c.350C>T p.P117L | Missense Mutation (SNP) | VAF 106/373 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.991); called by muse, varscan2
- ACTR1B | c.1062G>C p.K354N | Missense Mutation (SNP) | VAF 123/552 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- ADGRB1 | c.4144A>G p.T1382A | Missense Mutation (SNP) | VAF 149/436 reads (34%) | SIFT tolerated (0.82); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADGRL3 | c.1784G>T p.G595V (on ENST00000506720 / NM_001322402.2; = p.G527V on NM_015236.6) | Missense Mutation (SNP) | VAF 46/183 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); called by muse, mutect2, varscan2
- AHNAK | c.5003A>G p.K1668R | Missense Mutation (SNP) | VAF 142/668 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- AJUBA | c.592G>T p.G198* | Nonsense Mutation (SNP) | VAF 27/58 reads (47%) | called by muse, mutect2, varscan2
- ALMS1 | c.7675-2A>T p.X2559_splice | Splice Site (SNP) | VAF 72/213 reads (34%) | called by muse, mutect2, varscan2
- ALPK3 | c.3071T>A p.V1024E | Missense Mutation (SNP) | VAF 7/132 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2
- ANO5 | c.1285G>T p.E429* | Nonsense Mutation (SNP) | VAF 161/528 reads (30%) | called by muse, mutect2, varscan2
- AR | c.1415G>T p.G472V | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATP1A3 | c.147G>A p.M49I (on ENST00000545399 / NM_001256214.2; = p.M36I on NM_152296.5) | Missense Mutation (SNP) | VAF 198/710 reads (28%) | SIFT tolerated (0.84); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATP2A3 | c.850C>T p.H284Y | Missense Mutation (SNP) | VAF 32/646 reads (5%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.604); called by muse, mutect2
- ATP4B | c.680T>G p.L227R | Missense Mutation (SNP) | VAF 46/834 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.343); called by muse, mutect2
- ATP6V0A4 | c.884G>A p.W295* | Nonsense Mutation (SNP) | VAF 125/577 reads (22%) | called by muse, mutect2, varscan2
- AVPR2 | c.898G>A p.A300T | Missense Mutation (SNP) | VAF 32/49 reads (65%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.793); called by muse, mutect2, varscan2
- B4GALNT2 | c.68T>A p.V23D | Missense Mutation (SNP) | VAF 63/109 reads (58%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- BHLHA9 | c.584C>A p.P195Q | Missense Mutation (SNP) | VAF 22/34 reads (65%) | SIFT tolerated (0.32); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BMX | c.134_136del p.K45del | In Frame Del (DEL) | VAF 9/39 reads (23%) | called by mutect2, pindel, varscan2
- BPIFC | c.1316T>G p.L439R | Missense Mutation (SNP) | VAF 80/611 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CALB2 | c.67G>A p.E23K | Missense Mutation (SNP) | VAF 76/391 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.04); called by muse, varscan2
- CATSPERB | c.168+1del p.X56_splice | Splice Site (DEL) | VAF 11/29 reads (38%) | called by mutect2, pindel, varscan2
- CBLN2 | c.80G>A p.G27D | Missense Mutation (SNP) | VAF 25/157 reads (16%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CCT8 | c.472G>C p.D158H | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.214); called by muse, mutect2
- CD44 | c.563G>A p.S188N | Missense Mutation (SNP) | VAF 365/1089 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- CDC42BPG | c.3118A>G p.T1040A | Missense Mutation (SNP) | VAF 135/385 reads (35%) | SIFT tolerated (0.61); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CDH22 | c.1286+5G>T | Splice Region (SNP) | VAF 85/322 reads (26%) | called by muse, mutect2, varscan2
- CDHR3 | c.714-1G>T p.X238_splice | Splice Site (SNP) | VAF 41/177 reads (23%) | called by muse, mutect2, varscan2
- CDK3 | c.440G>C p.G147A | Missense Mutation (SNP) | VAF 104/370 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CELA3A | c.592G>T p.V198L | Missense Mutation (SNP) | VAF 40/147 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.166); called by muse, mutect2, varscan2
- CELSR2 | c.3723G>T p.M1241I | Missense Mutation (SNP) | VAF 184/589 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.218); called by muse, mutect2, varscan2
- CHD5 | c.4432C>G p.P1478A | Missense Mutation (SNP) | VAF 106/293 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CLSTN1 | c.612C>G p.I204M (on ENST00000377298 / NM_001009566.3; = p.I194M on NM_014944.4) | Missense Mutation (SNP) | VAF 98/324 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- CNTNAP4 | c.3085G>T p.A1029S | Missense Mutation (SNP) | VAF 38/228 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.06); called by muse, varscan2
- CNTNAP5 | c.1676G>A p.G559E | Missense Mutation (SNP) | VAF 30/378 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- COL5A1 | c.4159G>C p.G1387R | Missense Mutation (SNP) | VAF 69/539 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL6A6 | c.4129A>T p.N1377Y | Missense Mutation (SNP) | VAF 40/297 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- CSMD3 | c.3120C>A p.Y1040* (on ENST00000297405 / NM_001363185.1; = p.Y936* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 42/515 reads (8%) | called by muse, mutect2
- DDX51 | c.457G>C p.A153P | Missense Mutation (SNP) | VAF 55/182 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DERPC | c.869C>A p.A290D | Missense Mutation (SNP) | VAF 35/131 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- DHFR | c.420G>T p.M140I | Missense Mutation (SNP) | VAF 60/224 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, varscan2
- DIP2B | c.208del p.Q70Rfs*85 | Frame Shift Del (DEL) | VAF 39/327 reads (12%) | called by mutect2, pindel, varscan2
- DLGAP2 | c.1823C>G p.T608R | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.268); called by muse, mutect2
- DMBT1 | c.862del p.Q288Sfs*76 | Frame Shift Del (DEL) | VAF 88/593 reads (15%) | called by mutect2, pindel, varscan2
- DMD | c.2209C>A p.R737S | Missense Mutation (SNP) | VAF 29/148 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.704); called by muse, mutect2, varscan2
- DNAH8 | c.8914G>C p.G2972R | Missense Mutation (SNP) | VAF 180/605 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DPF3 | c.1105G>T p.E369* | Nonsense Mutation (SNP) | VAF 20/280 reads (7%) | called by muse, mutect2
- DPH1 | c.22G>T p.G8W | Missense Mutation (SNP) | VAF 175/354 reads (49%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- DPP10 | c.1171A>T p.K391* | Nonsense Mutation (SNP) | VAF 70/277 reads (25%) | called by muse, mutect2, varscan2
- DRGX | c.359del p.P120Rfs*24 | Frame Shift Del (DEL) | VAF 10/71 reads (14%) | called by mutect2, pindel, varscan2
- DZIP1L | c.1234+1G>A p.X412_splice | Splice Site (SNP) | VAF 33/103 reads (32%) | called by muse, mutect2, varscan2
- ENPP2 | c.834-2A>T p.X278_splice | Splice Site (SNP) | VAF 33/152 reads (22%) | called by muse, mutect2, varscan2
- EPHB1 | c.1513C>T p.Q505* | Nonsense Mutation (SNP) | VAF 10/160 reads (6%) | called by muse, mutect2
- ERO1B | c.928G>T p.E310* | Nonsense Mutation (SNP) | VAF 22/557 reads (4%) | called by muse, mutect2
- ESRRG | c.487A>T p.S163C | Missense Mutation (SNP) | VAF 77/402 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FAM234B | c.1678G>T p.V560F | Missense Mutation (SNP) | VAF 29/248 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.792); called by muse, mutect2, varscan2
- FCRL5 | c.1051G>T p.G351W | Missense Mutation (SNP) | VAF 47/235 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FLNC | c.1214C>A p.A405D | Missense Mutation (SNP) | VAF 79/727 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- FREM1 | c.3923G>T p.R1308M | Missense Mutation (SNP) | VAF 30/127 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- FREM3 | c.5871G>T p.K1957N | Missense Mutation (SNP) | VAF 151/617 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- FRG1 | c.743G>A p.R248K | Missense Mutation (SNP) | VAF 32/140 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- FSIP2 | c.10694T>A p.I3565N | Missense Mutation (SNP) | VAF 23/143 reads (16%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- GAN | c.876G>A p.M292I | Missense Mutation (SNP) | VAF 66/712 reads (9%) | SIFT tolerated (0.35); PolyPhen benign (0.001); called by muse, mutect2
- GK | c.175G>C p.E59Q | Missense Mutation (SNP) | VAF 82/173 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.236); called by muse, mutect2, varscan2
- GPATCH1 | c.556C>T p.P186S | Missense Mutation (SNP) | VAF 14/264 reads (5%) | SIFT tolerated (0.24); PolyPhen benign (0.024); called by muse, mutect2
- GPR26 | c.56C>T p.S19L | Missense Mutation (SNP) | VAF 15/206 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.194); called by muse, mutect2
- GRB10 | c.1418G>C p.G473A (on ENST00000398812; = p.G427A on NM_001001549.3) | Missense Mutation (SNP) | VAF 137/575 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- GRM1 | c.1218G>T p.Q406H | Missense Mutation (SNP) | VAF 100/513 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- GRM1 | c.1219G>T p.D407Y | Missense Mutation (SNP) | VAF 101/515 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- GSPT2 | c.1648G>A p.E550K | Missense Mutation (SNP) | VAF 18/204 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.731); called by muse, mutect2
- HDAC9 | c.2524C>G p.L842V | Missense Mutation (SNP) | VAF 55/317 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- HECW2 | c.2495C>A p.T832N | Missense Mutation (SNP) | VAF 37/163 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HERC2 | c.10912C>A p.L3638I | Missense Mutation (SNP) | VAF 20/245 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- HIRA | c.2883C>A p.D961E | Missense Mutation (SNP) | VAF 119/433 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- HNF4A | c.1258T>C p.W420R | Missense Mutation (SNP) | VAF 379/1515 reads (25%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- HRG | c.1351C>A p.H451N | Missense Mutation (SNP) | VAF 43/285 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.561); called by muse, mutect2, varscan2
- IL2RB | c.257G>T p.C86F | Missense Mutation (SNP) | VAF 46/451 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- ILF3 | c.2105G>T p.G702V | Missense Mutation (SNP) | VAF 37/290 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); called by muse, varscan2
- ITGA1 | c.2281T>A p.F761I | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.679); called by muse, mutect2, varscan2
- ITGA4 | c.2317G>A p.E773K | Missense Mutation (SNP) | VAF 22/197 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- KCNJ4 | c.292G>T p.G98C | Missense Mutation (SNP) | VAF 91/203 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.332); called by muse, mutect2, varscan2
- KIR2DL1 | c.722C>A p.P241H | Missense Mutation (SNP) | VAF 95/860 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- KLHDC7B | c.35A>T p.D12V (on ENST00000395676; = p.D653V on NM_138433.5) | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- LHX4 | c.319G>T p.D107Y | Missense Mutation (SNP) | VAF 140/540 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- LIG3 | c.1270T>A p.S424T | Missense Mutation (SNP) | VAF 39/347 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- LIN37 | c.483C>G p.Y161* | Nonsense Mutation (SNP) | VAF 61/300 reads (20%) | called by muse, mutect2, varscan2
- LRATD2 | c.524C>A p.P175Q | Missense Mutation (SNP) | VAF 146/411 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- LRIT2 | c.1259T>A p.V420E | Missense Mutation (SNP) | VAF 218/748 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- LRP1B | c.13760C>T p.P4587L | Missense Mutation (SNP) | VAF 43/173 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LRRC75A | c.154C>G p.H52D | Missense Mutation (SNP) | VAF 20/419 reads (5%) | SIFT tolerated (0.57); PolyPhen benign (0.205); called by muse, mutect2
- MAGEB6 | c.551C>A p.A184D | Missense Mutation (SNP) | VAF 40/78 reads (51%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.632); called by muse, mutect2, varscan2
- MAPKBP1 | c.1512-4G>T | Splice Region (SNP) | VAF 7/176 reads (4%) | called by muse, mutect2
- MEFV | c.1588-1G>C p.X530_splice | Splice Site (SNP) | VAF 93/467 reads (20%) | called by muse, mutect2, varscan2
- MICALL2 | c.797A>G p.D266G | Missense Mutation (SNP) | VAF 105/419 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- MME | c.1045C>A p.P349T | Missense Mutation (SNP) | VAF 108/365 reads (30%) | SIFT tolerated (0.55); PolyPhen benign (0.382); called by muse, mutect2, varscan2
- MTFR2 | c.686T>G p.V229G | Missense Mutation (SNP) | VAF 190/590 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- MTREX | c.2542A>G p.M848V | Missense Mutation (SNP) | VAF 79/216 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- MUC4 | c.11741C>A p.S3914Y | Missense Mutation (SNP) | VAF 128/731 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.618); called by muse, varscan2
- MYCBP2 | c.307C>G p.L103V (on ENST00000357337; = p.L141V on NM_015057.5) | Missense Mutation (SNP) | VAF 28/322 reads (9%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.931); called by muse, mutect2
- MYOZ3 | c.752T>C p.L251P | Missense Mutation (SNP) | VAF 51/110 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NAT1 | c.427C>G p.Q143E | Missense Mutation (SNP) | VAF 16/206 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2
- NBEA | c.6087del p.K2029Nfs*6 | Frame Shift Del (DEL) | VAF 36/98 reads (37%) | called by mutect2, pindel, varscan2
- NDNF | c.971G>T p.S324I | Missense Mutation (SNP) | VAF 41/231 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- NDRG1 | c.943+2T>A p.X315_splice | Splice Site (SNP) | VAF 158/768 reads (21%) | called by muse, varscan2
- NDST3 | c.583A>G p.I195V | Missense Mutation (SNP) | VAF 59/243 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- NEB | c.2639G>T p.R880L | Missense Mutation (SNP) | VAF 60/194 reads (31%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- NEURL1 | c.839C>G p.S280W | Missense Mutation (SNP) | VAF 53/257 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.466); called by muse, mutect2, varscan2
- NHEJ1 | c.229G>C p.D77H | Missense Mutation (SNP) | VAF 214/530 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- NLE1 | c.636G>T p.A212= | Splice Region (SNP) | VAF 39/116 reads (34%) | called by muse, mutect2, varscan2
- NLRP12 | c.1148A>T p.Q383L | Missense Mutation (SNP) | VAF 172/977 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- NOCT | c.98C>T p.S33F | Missense Mutation (SNP) | VAF 77/217 reads (35%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- NOTO | c.242C>G p.A81G | Missense Mutation (SNP) | VAF 24/306 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.133); called by muse, mutect2
- NR0B1 | c.1162A>T p.N388Y | Missense Mutation (SNP) | VAF 114/308 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NSDHL | c.20A>G p.E7G | Missense Mutation (SNP) | VAF 42/390 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- NTNG1 | c.1151G>T p.C384F | Missense Mutation (SNP) | VAF 57/284 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.757); called by muse, mutect2, varscan2
- NUP98 | c.2628G>C p.K876N | Missense Mutation (SNP) | VAF 49/139 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- OR14J1 | c.205C>A p.L69I | Missense Mutation (SNP) | VAF 50/502 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.015); called by muse, mutect2
- OR2L13 | c.799C>A p.P267T | Missense Mutation (SNP) | VAF 244/730 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.752); called by muse, mutect2, varscan2
- OR4A5 | c.161G>C p.G54A | Missense Mutation (SNP) | VAF 73/269 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- OR4C15 | c.730G>C p.D244H (on ENST00000314644; = p.D190H on NM_001001920.2) | Missense Mutation (SNP) | VAF 12/302 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.315); called by muse, mutect2
- OR4M1 | c.538G>A p.D180N | Missense Mutation (SNP) | VAF 153/688 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
- OR5B21 | c.83C>A p.A28E | Missense Mutation (SNP) | VAF 44/470 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.053); called by muse, mutect2
- OR5K3 | c.26T>A p.I9K | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, varscan2
- OR7D2 | c.295A>T p.T99S | Missense Mutation (SNP) | VAF 18/319 reads (6%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.057); called by muse, mutect2
- OSBP | c.383A>T p.H128L | Missense Mutation (SNP) | VAF 22/498 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- PATJ | c.2553G>A p.W851* | Nonsense Mutation (SNP) | VAF 61/380 reads (16%) | called by muse, mutect2, varscan2
- PCDHB10 | c.1498C>A p.L500I | Missense Mutation (SNP) | VAF 166/534 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- PCDHGB2 | c.1870G>C p.G624R | Missense Mutation (SNP) | VAF 137/408 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCLO | c.127G>T p.A43S | Missense Mutation (SNP) | VAF 80/984 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.942); called by muse, mutect2
- PHF21A | c.182A>G p.N61S | Missense Mutation (SNP) | VAF 46/904 reads (5%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.24); called by muse, mutect2
- PIF1 | c.98G>A p.R33Q | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT tolerated (0.66); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PIK3R1 | c.383C>A p.A128D | Missense Mutation (SNP) | VAF 165/503 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- PKHD1L1 | c.2980G>T p.G994* | Nonsense Mutation (SNP) | VAF 106/420 reads (25%) | called by muse, mutect2, varscan2
- PKHD1L1 | c.11035G>T p.A3679S | Missense Mutation (SNP) | VAF 122/364 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.724); called by muse, mutect2, varscan2
- PLCXD1 | c.89_93del p.R30Lfs*172 | Frame Shift Del (DEL) | VAF 67/435 reads (15%) | called by mutect2, pindel, varscan2
- PNPLA7 | c.3082-8G>T | Splice Region (SNP) | VAF 62/271 reads (23%) | called by muse, mutect2, varscan2
- POU3F2 | c.536C>A p.P179H | Missense Mutation (SNP) | VAF 164/635 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.57); called by muse, mutect2, varscan2
- PPM1E | c.1939C>A p.P647T | Missense Mutation (SNP) | VAF 79/284 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.329); called by muse, mutect2, varscan2
- PRR23B | c.400_418del p.D134Nfs*180 | Frame Shift Del (DEL) | VAF 105/580 reads (18%) | called by mutect2, pindel, varscan2
- PRSS36 | c.1172C>A p.A391E | Missense Mutation (SNP) | VAF 61/132 reads (46%) | SIFT tolerated (0.22); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- PTPDC1 | c.1766G>C p.R589T (on ENST00000375360 / NM_177995.3; = p.R641T on NM_152422.4) | Missense Mutation (SNP) | VAF 14/316 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PTPRU | c.2884C>T p.Q962* | Nonsense Mutation (SNP) | VAF 124/529 reads (23%) | called by muse, mutect2, varscan2
- QSER1 | c.1292C>T p.S431F (on ENST00000399302; = p.S560F on NM_001076786.3) | Missense Mutation (SNP) | VAF 12/167 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); called by muse, mutect2
- RAB20 | c.123C>G p.F41L | Missense Mutation (SNP) | VAF 31/681 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.903); called by muse, mutect2
- RAB6D | c.139G>T p.G47C | Missense Mutation (SNP) | VAF 52/329 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RERG | c.454G>A p.G152R | Missense Mutation (SNP) | VAF 57/221 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- RFX3 | c.1655T>C p.L552P | Missense Mutation (SNP) | VAF 115/434 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- RRP12 | c.2366A>T p.K789M | Missense Mutation (SNP) | VAF 25/204 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RTTN | c.1601C>G p.S534C | Missense Mutation (SNP) | VAF 26/343 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); called by muse, mutect2
- RXFP3 | c.845T>A p.I282N | Missense Mutation (SNP) | VAF 30/656 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); called by muse, mutect2
- RYR1 | c.1236G>T p.Q412H | Missense Mutation (SNP) | VAF 115/739 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- SCN1A | c.-49G>A | Splice Region (SNP) | VAF 38/123 reads (31%) | called by muse, mutect2, varscan2
- SCN7A | c.3965T>C p.V1322A | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- SCNN1G | c.1034C>G p.T345R | Missense Mutation (SNP) | VAF 16/304 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2
- SEC24B | c.1156G>A p.E386K | Missense Mutation (SNP) | VAF 10/113 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.073); called by muse, mutect2
- SEMG1 | c.209A>G p.H70R | Missense Mutation (SNP) | VAF 169/470 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- SETD5 | c.1085A>G p.H362R | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SEZ6L | c.241G>A p.G81S | Missense Mutation (SNP) | VAF 79/546 reads (14%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- SGK3 | c.144C>A p.F48L | Missense Mutation (SNP) | VAF 17/167 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.376); called by muse, varscan2
- SIGLEC11 | c.1021G>T p.G341C | Missense Mutation (SNP) | VAF 88/530 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- SIRPB1 | c.844C>A p.L282I | Missense Mutation (SNP) | VAF 51/202 reads (25%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- SLC22A18AS | c.212G>C p.R71T | Missense Mutation (SNP) | VAF 90/302 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- SLC26A8 | c.2140G>A p.D714N | Missense Mutation (SNP) | VAF 14/263 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.037); called by muse, mutect2
- SLC27A4 | c.215A>T p.E72V | Missense Mutation (SNP) | VAF 45/164 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- SLC37A4 | c.440T>C p.L147P | Missense Mutation (SNP) | VAF 57/484 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); called by muse, mutect2, varscan2
- SLC6A15 | c.421G>T p.G141C | Missense Mutation (SNP) | VAF 19/197 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- SLCO2A1 | c.1691C>A p.A564D | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SPATA16 | c.106C>T p.H36Y | Missense Mutation (SNP) | VAF 30/183 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- SUDS3 | c.819G>T p.Q273H | Missense Mutation (SNP) | VAF 115/470 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); called by mutect2, varscan2
- SVEP1 | c.9374C>A p.P3125Q | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SYNE1 | c.8236G>C p.E2746Q (on ENST00000367255 / NM_182961.4; = p.E2753Q on NM_033071.3) | Missense Mutation (SNP) | VAF 17/534 reads (3%) | SIFT tolerated (0.7); PolyPhen benign (0.018); called by muse, mutect2
- SYNPO | c.2732C>G p.S911C (on ENST00000394243 / NM_001166208.2; = p.S667C on NM_007286.6) | Missense Mutation (SNP) | VAF 31/565 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2
- TAL1 | c.949C>T p.L317F | Missense Mutation (SNP) | VAF 118/425 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- TAS2R43 | c.184T>A p.L62I | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.007); called by mutect2, varscan2
- TBX18 | c.695G>T p.G232V | Missense Mutation (SNP) | VAF 106/454 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TIE1 | c.1795T>G p.S599A | Missense Mutation (SNP) | VAF 26/443 reads (6%) | SIFT tolerated (0.55); PolyPhen benign (0.055); called by muse, mutect2
- TLN1 | c.442G>C p.D148H | Missense Mutation (SNP) | VAF 25/233 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.278); called by muse, mutect2, varscan2
- TMEM236 | c.175G>T p.A59S | Missense Mutation (SNP) | VAF 165/823 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- TRAPPC9 | c.2170G>A p.V724I | Missense Mutation (SNP) | VAF 144/341 reads (42%) | SIFT tolerated (0.51); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- TRIM32 | c.66C>G p.I22M | Missense Mutation (SNP) | VAF 12/288 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- TRIO | c.9061C>G p.Q3021E | Missense Mutation (SNP) | VAF 58/706 reads (8%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.963); called by muse, mutect2
- TULP4 | c.2000A>C p.E667A | Missense Mutation (SNP) | VAF 58/189 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- UNC13A | c.3773A>G p.N1258S | Missense Mutation (SNP) | VAF 15/225 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- UNC79 | c.7006C>A p.H2336N (on ENST00000393151 / NM_001346218.2; = p.H2159N on NM_020818.5) | Missense Mutation (SNP) | VAF 101/272 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- URGCP | c.2332_2343del p.L778_L781del (on ENST00000453200 / NM_001077663.3; = p.L769_L772del on NM_017920.4) | In Frame Del (DEL) | VAF 49/450 reads (11%) | called by mutect2, pindel
- VPS52 | c.1621-18_1621-2del p.X541_splice | Splice Site (DEL) | VAF 49/217 reads (23%) | called by mutect2, pindel, varscan2
- VSIG4 | c.1021A>T p.S341C | Missense Mutation (SNP) | VAF 25/214 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.417); called by muse, mutect2, varscan2
- VWA5B1 | c.1574T>A p.M525K | Missense Mutation (SNP) | VAF 27/129 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2
- ZCCHC13 | c.381G>T p.Q127H | Missense Mutation (SNP) | VAF 130/251 reads (52%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- ZFYVE9 | c.3334-2A>T p.X1112_splice | Splice Site (SNP) | VAF 37/114 reads (32%) | called by muse, mutect2, varscan2
- ZNF114 | c.560_570del p.V187Efs*22 | Frame Shift Del (DEL) | VAF 55/269 reads (20%) | called by pindel, varscan2*
- ZNF157 | c.1002A>T p.E334D | Missense Mutation (SNP) | VAF 45/106 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF256 | c.1190A>T p.H397L | Missense Mutation (SNP) | VAF 20/170 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- ZNF367 | c.115C>G p.P39A | Missense Mutation (SNP) | VAF 48/187 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ZNF514 | c.38G>T p.W13L | Missense Mutation (SNP) | VAF 91/533 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- ZNF585A | c.1826G>T p.S609I (on ENST00000292841 / NM_001288800.2; = p.S554I on NM_152655.3) | Missense Mutation (SNP) | VAF 46/174 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ZNF831 | c.3430C>A p.P1144T | Missense Mutation (SNP) | VAF 62/259 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZYG11B | c.1947-2A>G p.X649_splice | Splice Site (SNP) | VAF 91/273 reads (33%) | called by muse, mutect2, varscan2
- ADGRE1 | c.2463G>T p.V821= | Silent (SNP) | VAF 76/252 reads (30%) | called by muse, varscan2
- ADGRG4 | c.1884T>G p.A628= | Silent (SNP) | VAF 13/196 reads (7%) | catalogued as COSV54959699; called by muse, mutect2
- AGTR1 | c.570C>A p.T190= | Silent (SNP) | VAF 6/117 reads (5%) | catalogued as COSV62559125; called by muse, mutect2
- AMIGO1 | c.255G>C p.L85= | Silent (SNP) | VAF 116/422 reads (27%) | called by muse, mutect2, varscan2
- ANO1 | c.1320C>T p.L440= | Silent (SNP) | VAF 113/539 reads (21%) | called by muse, mutect2, varscan2
- APOB | c.3282G>T p.L1094= | Silent (SNP) | VAF 94/238 reads (39%) | called by muse, mutect2, varscan2
- ASAH2 | c.765C>A p.I255= | Silent (SNP) | VAF 42/1080 reads (4%) | called by muse, mutect2
- BHMT2 | c.177T>A p.L59= | Silent (SNP) | VAF 63/134 reads (47%) | called by muse, mutect2, varscan2
- CACNA1A | c.4830C>T p.S1610= | Silent (SNP) | VAF 16/99 reads (16%) | called by muse, mutect2, varscan2
- CACNA1E | c.5754G>A p.L1918= | Silent (SNP) | VAF 101/278 reads (36%) | called by muse, mutect2, varscan2
- CCDC172 | c.39C>A p.T13= | Silent (SNP) | VAF 130/541 reads (24%) | catalogued as COSV60938128; called by muse, mutect2, varscan2
- CCNT1 | c.885C>G p.T295= | Silent (SNP) | VAF 32/380 reads (8%) | called by muse, mutect2
- CDH22 | c.1584C>T p.P528= | Silent (SNP) | VAF 22/426 reads (5%) | called by muse, mutect2
- CES1 | c.1302C>T p.A434= (on ENST00000361503 / NM_001025194.2; = p.A433= on NM_001266.5) | Silent (SNP) | VAF 52/434 reads (12%) | called by muse, mutect2, varscan2
- CHRM2 | c.798C>A p.P266= | Silent (SNP) | VAF 60/288 reads (21%) | catalogued as rs1262103632, COSV57784562; called by muse, varscan2
- CNTNAP4 | c.3084T>G p.A1028= | Silent (SNP) | VAF 37/226 reads (16%) | called by muse, varscan2
- CPS1 | c.2400T>A p.A800= | Silent (SNP) | VAF 86/456 reads (19%) | called by muse, mutect2, varscan2
- DNAH5 | c.5253T>C p.S1751= | Silent (SNP) | VAF 32/616 reads (5%) | called by muse, mutect2
- ELF5 | c.244T>C p.L82= (on ENST00000312319 / NM_198381.2; = p.L72= on NM_001422.4) | Silent (SNP) | VAF 225/624 reads (36%) | called by muse, mutect2, varscan2
- EPHA8 | c.2874T>C p.S958= | Silent (SNP) | VAF 210/828 reads (25%) | called by muse, varscan2
- EPHA8 | c.2875C>T p.L959= | Silent (SNP) | VAF 210/832 reads (25%) | catalogued as rs747764837; called by muse, varscan2
- ERC2 | c.2526T>A p.I842= | Silent (SNP) | VAF 36/263 reads (14%) | called by muse, mutect2, varscan2
- FAM135B | c.3840G>T p.L1280= | Silent (SNP) | VAF 82/317 reads (26%) | called by muse, mutect2, varscan2
- FLG | c.1317C>A p.G439= | Silent (SNP) | VAF 166/722 reads (23%) | called by muse, mutect2, varscan2
- GGT7 | c.825C>T p.A275= | Silent (SNP) | VAF 31/110 reads (28%) | catalogued as rs755512700, COSV60542969; called by muse, varscan2
- GREM2 | c.189C>T p.T63= | Silent (SNP) | VAF 20/341 reads (6%) | catalogued as rs1253433623, COSV100547419; called by muse, mutect2
- HNF4G | c.564C>G p.S188= (on ENST00000354370 / NM_001330561.2; = p.S235= on NM_004133.5) | Silent (SNP) | VAF 38/191 reads (20%) | catalogued as COSV100584852; called by muse, mutect2, varscan2
- HSPA12A | c.1233C>T p.D411= | Silent (SNP) | VAF 26/276 reads (9%) | called by muse, mutect2
- IGSF11 | c.42C>T p.L14= | Silent (SNP) | VAF 31/104 reads (30%) | catalogued as rs778886399; called by muse, mutect2, varscan2
- IZUMO3 | c.348G>T p.L116= | Silent (SNP) | VAF 62/238 reads (26%) | called by muse, mutect2, varscan2
- KCNJ3 | c.891C>T p.V297= | Silent (SNP) | VAF 63/332 reads (19%) | called by muse, mutect2, varscan2
- KLHL4 | c.1284G>T p.V428= | Silent (SNP) | VAF 37/98 reads (38%) | called by muse, mutect2, varscan2
- LARGE1 | c.1014C>T p.F338= | Silent (SNP) | VAF 16/187 reads (9%) | catalogued as rs758924905; called by muse, mutect2
- LMAN1L | c.1542T>A p.I514= | Silent (SNP) | VAF 96/203 reads (47%) | called by muse, mutect2, varscan2
- MAT1A | c.177G>C p.V59= | Silent (SNP) | VAF 62/794 reads (8%) | catalogued as rs1564647848; called by muse, mutect2
- MROH2B | c.1329C>A p.V443= | Silent (SNP) | VAF 72/352 reads (20%) | called by muse, mutect2, varscan2
- MYO1C | c.1644G>C p.A548= (on ENST00000648651 / NM_001080779.2; = p.A513= on NM_033375.5) | Silent (SNP) | VAF 249/511 reads (49%) | catalogued as rs551011507, COSV62998433; called by muse, varscan2
- NBEAL2 | c.3396G>C p.A1132= | Silent (SNP) | VAF 14/140 reads (10%) | called by muse, mutect2
- NLRC3 | c.2103C>A p.L701= | Silent (SNP) | VAF 46/206 reads (22%) | called by muse, mutect2, varscan2
- OR10A6 | c.450C>A p.A150= | Silent (SNP) | VAF 50/251 reads (20%) | called by muse, mutect2, varscan2
- OR5D18 | c.201C>A p.L67= | Silent (SNP) | VAF 46/164 reads (28%) | catalogued as rs1412780648, COSV100450792; called by muse, mutect2, varscan2
- OR5M1 | c.639C>T p.I213= | Silent (SNP) | VAF 169/510 reads (33%) | called by muse, mutect2, varscan2
- PABPC5 | c.708G>T p.G236= | Silent (SNP) | VAF 96/177 reads (54%) | called by muse, mutect2, varscan2
- PARP4 | c.3204C>A p.A1068= | Silent (SNP) | VAF 27/242 reads (11%) | catalogued as rs748310142; called by muse, mutect2, varscan2
- PKHD1L1 | c.8130C>T p.V2710= | Silent (SNP) | VAF 112/642 reads (17%) | catalogued as rs770989608, COSV65745274; called by muse, mutect2, varscan2
- PLCXD3 | c.519G>T p.A173= | Silent (SNP) | VAF 20/290 reads (7%) | catalogued as rs377065100, COSV60605164; called by muse, mutect2
- PPP2R2C | c.24G>A p.R8= | Silent (SNP) | VAF 156/505 reads (31%) | called by muse, mutect2, varscan2
- RBM24 | c.411C>G p.V137= (on ENST00000379052 / NM_001143942.2; = p.V92= on NM_153020.2) | Silent (SNP) | VAF 96/343 reads (28%) | catalogued as rs1453699863; called by muse, mutect2, varscan2
- RBMXL3 | c.1272G>A p.E424= | Silent (SNP) | VAF 166/298 reads (56%) | called by muse, mutect2, varscan2
- RIOK3 | c.1122A>G p.E374= | Silent (SNP) | VAF 87/182 reads (48%) | called by muse, mutect2, varscan2
- RRP9 | c.24T>A p.R8= | Silent (SNP) | VAF 115/252 reads (46%) | called by muse, mutect2, varscan2
- SATL1 | c.522C>A p.P174= (on ENST00000395409; = p.P361= on NM_001012980.2) | Silent (SNP) | VAF 85/142 reads (60%) | called by muse, mutect2, varscan2
- SLC6A20 | c.636C>A p.I212= | Silent (SNP) | VAF 62/167 reads (37%) | called by muse, mutect2, varscan2
- SOBP | c.2388G>A p.L796= | Silent (SNP) | VAF 58/866 reads (7%) | called by muse, mutect2
- SPARCL1 | c.192C>A p.S64= | Silent (SNP) | VAF 48/187 reads (26%) | catalogued as rs11557438; called by muse, mutect2, varscan2
- STH | c.225C>T p.P75= | Silent (SNP) | VAF 258/429 reads (60%) | called by muse, mutect2, varscan2
- TFCP2L1 | c.957C>T p.H319= | Silent (SNP) | VAF 109/431 reads (25%) | catalogued as rs1367351314; called by muse, mutect2, varscan2
- TXNDC11 | c.2598G>A p.R866= (on ENST00000356957 / NM_001303447.2; = p.R839= on NM_015914.7 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 61/450 reads (14%) | called by muse, mutect2, varscan2
- ZBTB7A | c.756C>T p.P252= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as rs1413780305; called by muse, mutect2, varscan2
- ZNF423 | c.1758G>T p.L586= (on ENST00000563137 / NM_001379286.1; = p.L578= on NM_015069.4) | Silent (SNP) | VAF 73/491 reads (15%) | called by muse, mutect2, varscan2
- ZNF700 | c.1263G>A p.K421= | Silent (SNP) | VAF 212/782 reads (27%) | catalogued as rs757464394; called by muse, mutect2, varscan2
- AC127029.3 | c.*31C>T | 3'UTR (SNP) | VAF 88/200 reads (44%) | catalogued as rs1340006815; called by muse, mutect2, varscan2
- ADGRA1 | c.4-3772G>C | Intron (SNP) | VAF 70/473 reads (15%) | called by muse, mutect2, varscan2
- AGXT2 | c.675+34A>T | Intron (SNP) | VAF 138/466 reads (30%) | called by muse, mutect2, varscan2
- AL021937.5 | n.35_53del | RNA (DEL) | VAF 17/74 reads (23%) | called by mutect2, pindel, varscan2
- AL353804.6 | chrX:73826323 G>T | 3'Flank (SNP) | VAF 22/436 reads (5%) | called by muse, mutect2
- BCO1 | c.*6T>C | 3'UTR (SNP) | VAF 7/114 reads (6%) | called by muse, mutect2
- CARS2 | c.1417-227A>T | Intron (SNP) | VAF 85/526 reads (16%) | catalogued as rs1443682416; called by muse, mutect2, varscan2
- CHRNA4 | c.*294G>A | 3'UTR (SNP) | VAF 106/1986 reads (5%) | called by muse, mutect2
- CICP28 | chr7:56812163 G>A | 3'Flank (SNP) | VAF 34/184 reads (18%) | called by muse, mutect2, varscan2
- CLK2P1 | n.576C>A | RNA (SNP) | VAF 120/543 reads (22%) | catalogued as rs776677842; called by muse, mutect2, varscan2
- CTSK | c.-1-630_-1-618del | Intron (DEL) | VAF 34/98 reads (35%) | called by mutect2, pindel
- CXCL8 | c.*25A>G | 3'UTR (SNP) | VAF 17/88 reads (19%) | called by muse, mutect2, varscan2
- DCUN1D2 | c.3+189C>T | Intron (SNP) | VAF 120/180 reads (67%) | called by muse, mutect2, varscan2
- DNAH14 | c.6033+6559G>C | Intron (SNP) | VAF 96/249 reads (39%) | called by muse, mutect2, varscan2
- EPCAM | c.*30G>A | 3'UTR (SNP) | VAF 20/176 reads (11%) | called by muse, varscan2
- FAP | c.1402+556C>A | Intron (SNP) | VAF 92/329 reads (28%) | called by muse, mutect2, varscan2
- FGFR1 | c.358+18del | Intron (DEL) | VAF 15/100 reads (15%) | called by mutect2, pindel, varscan2
- GNAS | chr20:58889217 G>T | 5'Flank (SNP) | VAF 217/572 reads (38%) | called by muse, mutect2, varscan2
- GVINP1 | n.3410G>T | RNA (SNP) | VAF 66/213 reads (31%) | called by muse, mutect2, varscan2
- HECTD1 | c.4982-523G>C | Intron (SNP) | VAF 28/122 reads (23%) | catalogued as rs773461546; called by muse, varscan2
- INS-IGF2 | c.-1C>T | 5'UTR (SNP) | VAF 22/340 reads (6%) | called by muse, mutect2
- KCNK17 | c.689-697T>C | Intron (SNP) | VAF 63/591 reads (11%) | called by muse, mutect2, varscan2
- KLHL7 | c.*803C>G | 3'UTR (SNP) | VAF 21/93 reads (23%) | called by muse, mutect2, varscan2
- LINC00602 | n.1083C>T | RNA (SNP) | VAF 29/108 reads (27%) | called by muse, mutect2, varscan2
- LINC00602 | n.1178A>G | RNA (SNP) | VAF 56/222 reads (25%) | called by muse, varscan2
- MFRP | chr11:119344320 G>T | 5'Flank (SNP) | VAF 269/609 reads (44%) | called by muse, mutect2, varscan2
- MIR297 | n.46G>A | RNA (SNP) | VAF 5/21 reads (24%) | called by muse, mutect2, varscan2
- NECTIN3 | c.160+5035G>T | Intron (SNP) | VAF 10/256 reads (4%) | called by muse, mutect2
- NXF5 | n.1467G>T | RNA (SNP) | VAF 99/192 reads (52%) | called by muse, mutect2, varscan2
- PDPK1 | c.1344-2785C>G | Intron (SNP) | VAF 23/368 reads (6%) | called by muse, mutect2
- PICK1 | c.283-52_283-15del | Intron (DEL) | VAF 82/442 reads (19%) | called by mutect2, pindel
- PITPNM3 | c.*23G>C | 3'UTR (SNP) | VAF 5/18 reads (28%) | called by muse, mutect2, varscan2
- POM121L2 | c.*11C>A | 3'UTR (SNP) | VAF 28/134 reads (21%) | called by muse, varscan2
- PRAME | chr22:22559378 T>A | 5'Flank (SNP) | VAF 20/203 reads (10%) | called by muse, mutect2
- RBMS2 | c.543-848G>T | Intron (SNP) | VAF 10/69 reads (14%) | called by muse, mutect2, varscan2
- SCML4 | c.*15C>A | 3'UTR (SNP) | VAF 256/901 reads (28%) | called by muse, mutect2, varscan2
- SEPTIN9 | c.-11A>T | 5'UTR (SNP) | VAF 21/482 reads (4%) | called by muse, mutect2
- SLC9A3R1 | c.*25G>T | 3'UTR (SNP) | VAF 59/302 reads (20%) | called by muse, mutect2, varscan2
- STMN4 | c.510+15G>T | Intron (SNP) | VAF 68/311 reads (22%) | called by muse, mutect2, varscan2
- STMN4 | c.510+14G>C | Intron (SNP) | VAF 68/316 reads (22%) | called by muse, mutect2, varscan2
- TFR2 | c.2136+19C>G | Intron (SNP) | VAF 14/198 reads (7%) | called by muse, mutect2
- USH1C | c.*12G>A | 3'UTR (SNP) | VAF 257/807 reads (32%) | catalogued as rs1295816654; called by muse, mutect2, varscan2
